Surgical pathology report (de-identified scan), TCGA case TCGA-WE-A8K4, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site  Norfolk and Norwich Hospital, specimen TCGA-WE-A8K4-01A (Primary Tumor).

[page 1 of 4]
Surgical Histology

Surgical Histology

ADDRESS FOR REPORT:

Copy To: n/a

HISTOPATHOLOGY REPORT

CASE HISTORY:

?BCC. 8mm punch.

MACROSCOPIC:

8 mm punch biopsy.

MICROSCOPY:

A punch excision of skin showing a benign early trichilemmoma which appears completely excised. There is no evidence of dysplasia or malignancy.

DIAGNOSIS:

8MM PUNCH EXCISION OF SKIN (RIGHT CHEEK): TRICHILEMMOMA.

REPORTED BY:

ICD-O-3
Melanoma, nodular
8 721/3
Site Skin, R Arm
C44.6
JpV 11/22/13

Surgical Histology

Surgical Histology

ADDRESS FOR REPORT:

Copy To: n/a

Report to Cancer Registry

HISTOPATHOLOGY REPORT

CASE HISTORY:

Superficial mass for many years. Ulcerated skin over mass. ? Fat necrosis in old lipoma.

MACROSCOPIC:

[page 2 of 4]
One core of tissue, 0.9 cm, plus frags.

MICROSCOPY:

A fragmented needle core biopsy of fibrofatty tissue, which includes parts of a malignant neoplasm. It is composed of pleomorphic large epithelioid and spindle-cell shaped cells. They have abundant eosinophilic (sometimes faintly yellowish) cytoplasm and large eosinophilic nucleoli. Elsewhere, the tissue shows chronic fibro-inflammatory changes with focal yellowish brown pigment (probably blood-derived).

There are various possibilities, of which malignant melanoma or metastatic carcinoma are likely contenders. Are there any clinical or historical clues?

Please regard this as a provisional and preliminary urgent report. Definitive diagnosis will depend upon immunohistochemical staining. A further report will follow.

DIAGNOSIS:

CORE BIOPSY OF MASS, RIGHT ARM

REPORTED BY:

SUPPLEMENTARY REPORT:

Histochemical and immunohistochemical staining has been undertaken.

No definite melanin is recognised within the tumour cells. They are strongly immunostained in S100 protein, melan A, and HMB-45 preparations. They do not stain for keratins. These observations imply that the tumour is a malignant melanoma. The history provided seems odd in that context.

DIAGNOSIS:

CORE BIOPSY OF MASS, RIGHT ARM: MALIGNANT MELANOMA

REPORTED BY:

REPORT DATE:

MALIGNANT MELANOMA MINIMUM DATA SET

LAB NUMBER:

PRIVATE PATIENT: Yes

ADDRESS FOR REPORT:

CLINICAL HISTORY:

: Melanoma right upper arm.

MACROSCOPIC:

Large disc of skin 12 x 17 x 3.5 cm. Skin sutured centrally with underlying firm tumour, 4 cm maximum diameter, which has been sliced open, disrupted Distance of tumour to margin approximately 4

[page 3 of 4]
cm,
minimum 2.0 cm. Deep margin black. Peripheral margin yellow.
Closest margin is A and B. A and B continuous. C and D continuous.
E and F = random tumour.

MICROSCOPIC:

Tumour type	Nodular
Growth phase	Vertical
Breslow thickness (mm)	12.00
Mitotic rate (/sq mm)	4
Regression	Absent
Lymphovascular invasion	Absent
Perineural invasion	Absent
Microsatellites	Absent
Coexistent naevus	Absent
Tumour infiltrating lymphocytes	Non-brisk
Completely Excised	Yes
Deep margin (mm)	0.3
Circumferential margin (mm)	20.0
Stage	pT4a

COMMENT:

Skin sliced open before receipt---ulceration can not be excluded.

The possibility of a metastatic lesion should be excluded clinically.

DIAGNOSIS:

Skin of Right Arm: Malignant Melanoma.

REPORTED BY:

ADDITIONAL REPORT:

BRAF immunostain is negative.

This case was sent to
testing.

for BRAF

. BRAF gene analysis using PCR for
Codon 600, Exon of BRAF gene showed no evidence of mutation.

Surgical Histology
Surgical Histology

[page 4 of 4]
Report to Cancer Registry

HISTOPATHOLOGY REPORT

LAB No: Lab No.
Hosp No.

CASE HISTORY:

Prostate chippings.
Catheter in-situ for retention.
DRE hard prostate.
PSA awaited ?Ca prostate.

MACROSCOPIC:

Prostate chips weighing 24g.

MICROSCOPY:

Shows infiltrating adenocarcinoma with more than 90% of the prostate chips. The features are those of Gleason 4+4=8 with tertiary pattern 5.

DIAGNOSIS:

PROSTATE CHIPPINGS: INFILTRATING ADENOCARCINOMA IN MORE THAN 90% OF TISSUE. pT1b.

REPORTED BY:

Consultant Histopathologist
Consultant Histopathologist

REPORT DATE:

Source: NCI Genomic Data Commons file df0d9103-eef9-4563-bb28-39d1d8694b3b (TCGA-WE-A8K4.1B421DA3-59DD-4246-8D3B-58F4AE13F36B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).